Somatic mutation profile of tumor specimen C3L-01312-01 (aliquot CPT0063670006) from CPTAC case C3L-01312, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Age at diagnosis: 56.8 years (20,729 days).
Specimen C3L-01312-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) da8e1298-fe69-451e-a388-0da5a03c1a8b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01312-31 (Blood Derived Normal), aliquot CPT0065300002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e9237e1d-934c-4e44-a0df-afc428b0ae70

The open-access MAF lists 66 somatic variants for this specimen: 47 protein-altering or splice-affecting, 13 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 13, Intron 3, Frame Shift Del 2, Splice Site 2, 5'UTR 1, Frame Shift Ins 1, 3'UTR 1, Nonstop Mutation 1, RNA 1, Nonsense Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 57/212 reads (27%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTEN | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 31/201 reads (15%) | hotspot (GDC flag); catalogued as rs121909219, CM971277, COSV64288653, COSV64291717, COSV64302607, COSV64306399, COSV64306519, COSV64311585, COSV99058021; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- SPOP | c.349A>G p.M117V | Missense Mutation (SNP) | VAF 38/111 reads (34%) | hotspot (GDC flag); SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV61652945; called by muse, mutect2, varscan2
- ADAMTS16 | c.1987C>T p.R663W | Missense Mutation (SNP) | VAF 48/222 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs550837516, COSV56982433; called by muse, mutect2, varscan2
- ADRB3 | c.1201G>A p.D401N | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as COSV61462404; called by muse, mutect2, varscan2
- AP5B1 | c.622G>T p.G208W | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.475); catalogued as rs763900912, COSV100376005; called by muse, mutect2, varscan2
- ARID3B | c.149C>T p.P50L | Missense Mutation (SNP) | VAF 57/321 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.038); catalogued as rs754732175; called by muse, mutect2, varscan2
- ARMC7 | c.304C>T p.L102F | Missense Mutation (SNP) | VAF 166/328 reads (51%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.78); catalogued as rs1568020068; called by muse, mutect2, varscan2
- ATRAID | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 69/620 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs201195587; called by muse, mutect2, varscan2
- CEACAM5 | c.1826C>T p.A609V | Missense Mutation (SNP) | VAF 94/437 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.07); catalogued as rs200399646, COSV55751813; called by muse, mutect2, varscan2
- DIPK1C | c.1024G>A p.V342I | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.087); catalogued as rs774528542; called by muse, mutect2
- FAM126A | c.892A>G p.T298A | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs758708291; called by muse, mutect2, varscan2
- GABBR2 | c.1235C>T p.T412M | Missense Mutation (SNP) | VAF 88/346 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs755692994, COSV52292416; called by muse, mutect2, varscan2
- GRIN2A | c.449C>A p.S150Y | Missense Mutation (SNP) | VAF 32/233 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV58059135; called by muse, mutect2, varscan2
- IGSF8 | c.1699C>T p.P567S | Missense Mutation (SNP) | VAF 54/449 reads (12%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as rs1367176271; called by muse, mutect2, varscan2
- KAT6A | c.2303A>G p.D768G | Missense Mutation (SNP) | VAF 14/366 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.24); catalogued as rs1456937248; called by muse, mutect2
- LAMC2 | c.514G>T p.G172C | Missense Mutation (SNP) | VAF 75/356 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51455211, COSV51460598; called by muse, mutect2, varscan2
- MRPL13 | c.535T>A p.*179Kext*8 | Nonstop Mutation (SNP) | VAF 13/68 reads (19%) | catalogued as COSV60367802; called by muse, mutect2, varscan2
- MYEF2 | c.548G>A p.R183H | Missense Mutation (SNP) | VAF 30/213 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs773163913, COSV51047562; called by muse, mutect2, varscan2
- PCDH15 | c.2624C>T p.S875L | Missense Mutation (SNP) | VAF 36/235 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.962); catalogued as rs201328768, COSV57300062; called by muse, mutect2, varscan2
- PIP4P2 | c.161C>T p.P54L | Missense Mutation (SNP) | VAF 36/186 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.127); catalogued as rs1338877144, COSV53437689; called by muse, mutect2, varscan2
- PTEN | c.262T>G p.Y88D | Missense Mutation (SNP) | VAF 60/164 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as CM032997, COSV64292718, COSV64295467; called by muse, mutect2, varscan2
- SLC26A8 | c.2446C>T p.R816W | Missense Mutation (SNP) | VAF 61/265 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as rs754358341, COSV100839487; called by muse, mutect2, varscan2
- TTN | c.19445G>A p.R6482Q (on ENST00000591111; = p.R5555Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/78 reads (14%) | PolyPhen benign (0.331); catalogued as rs780069933; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZBTB43 | c.1201G>A p.G401S | Missense Mutation (SNP) | VAF 31/198 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.273); catalogued as rs1012112533, COSV65094819; called by muse, mutect2, varscan2
- CACNA1B | c.610T>C p.S204P | Missense Mutation (SNP) | VAF 76/315 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CBX2 | c.170C>A p.A57D | Missense Mutation (SNP) | VAF 22/446 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CCNE1 | c.332C>A p.A111E | Missense Mutation (SNP) | VAF 6/115 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2
- CDC42BPA | c.988G>C p.G330R | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CENPT | c.703+7T>C | Splice Region (SNP) | VAF 48/247 reads (19%) | called by muse, mutect2, varscan2
- CHRM4 | c.398G>A p.C133Y | Missense Mutation (SNP) | VAF 51/630 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.95); called by muse, mutect2
- DHX30 | c.1477C>T p.R493C (on ENST00000445061 / NM_138615.3; = p.R454C on NM_014966.3) | Missense Mutation (SNP) | VAF 115/593 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DKC1 | c.1322C>T p.A441V | Missense Mutation (SNP) | VAF 28/745 reads (4%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2
- FCRL6 | c.25C>T p.L9F | Missense Mutation (SNP) | VAF 29/356 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.007); called by muse, mutect2
- IRS4 | c.1499del p.G500Afs*111 | Frame Shift Del (DEL) | VAF 244/1111 reads (22%) | called by mutect2, pindel, varscan2
- IRX6 | c.721+2T>C p.X241_splice | Splice Site (SNP) | VAF 9/79 reads (11%) | called by muse, mutect2, varscan2
- LAMA2 | c.5071+2T>A p.X1691_splice | Splice Site (SNP) | VAF 82/365 reads (22%) | called by muse, mutect2, varscan2
- MAGEE1 | c.987C>A p.S329R | Missense Mutation (SNP) | VAF 77/433 reads (18%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MSX1 | c.44_45dup p.V16Kfs*145 | Frame Shift Ins (INS) | VAF 74/361 reads (20%) | called by mutect2, pindel, varscan2
- MYH9 | c.2485C>T p.R829W | Missense Mutation (SNP) | VAF 36/626 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PCDHGB5 | c.2065G>T p.V689L | Missense Mutation (SNP) | VAF 121/573 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- RPL10A | c.331T>G p.L111V | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.687); called by muse, mutect2, varscan2
- SETDB1 | c.2643del p.S881Rfs*3 | Frame Shift Del (DEL) | VAF 17/95 reads (18%) | called by mutect2, pindel, varscan2
- SKOR2 | c.1174G>T p.G392W | Missense Mutation (SNP) | VAF 15/156 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- SLC3A1 | c.200G>A p.G67E | Missense Mutation (SNP) | VAF 99/409 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SYNE1 | c.12389A>G p.Q4130R (on ENST00000367255 / NM_182961.4; = p.Q4059R on NM_033071.3) | Missense Mutation (SNP) | VAF 17/199 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.151); called by muse, mutect2
- VWF | c.3707C>A p.A1236D | Missense Mutation (SNP) | VAF 114/926 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ACSBG1 | c.1665C>T p.D555= | Silent (SNP) | VAF 44/198 reads (22%) | catalogued as rs377622035; called by muse, mutect2, varscan2
- ARHGEF17 | c.5847G>A p.S1949= | Silent (SNP) | VAF 71/583 reads (12%) | catalogued as rs751926590; called by muse, mutect2, varscan2
- DOP1B | c.2304C>T p.S768= | Silent (SNP) | VAF 18/72 reads (25%) | catalogued as rs750684828; called by muse, mutect2
- HAS2 | c.453C>T p.N151= | Silent (SNP) | VAF 39/184 reads (21%) | called by muse, mutect2, varscan2
- IMP4 | c.414C>T p.V138= | Silent (SNP) | VAF 14/397 reads (4%) | catalogued as rs1384406840; called by muse, mutect2
- JAKMIP3 | c.1764G>A p.E588= | Silent (SNP) | VAF 143/340 reads (42%) | catalogued as rs987333114; called by muse, mutect2, varscan2
- MYLK4 | c.450C>T p.N150= | Silent (SNP) | VAF 26/235 reads (11%) | catalogued as rs369334810; called by muse, mutect2, varscan2
- PCDHA10 | c.2166G>A p.S722= | Silent (SNP) | VAF 32/324 reads (10%) | catalogued as COSV56539283; called by muse, mutect2, varscan2
- PEAR1 | c.2280C>T p.G760= | Silent (SNP) | VAF 125/736 reads (17%) | called by muse, mutect2, varscan2
- PRKDC | c.1512A>G p.E504= | Silent (SNP) | VAF 16/76 reads (21%) | catalogued as rs768499170; called by muse, mutect2, varscan2
- SPEG | c.1080G>A p.S360= | Silent (SNP) | VAF 99/412 reads (24%) | catalogued as COSV56675801; called by muse, mutect2, varscan2
- WNK2 | c.2244C>T p.P748= | Silent (SNP) | VAF 62/279 reads (22%) | catalogued as rs754878750; called by muse, mutect2, varscan2
- ZNF648 | c.1236C>T p.R412= | Silent (SNP) | VAF 10/222 reads (5%) | called by muse, mutect2
- CHPF2 | c.*73T>G | 3'UTR (SNP) | VAF 29/158 reads (18%) | called by muse, mutect2, varscan2
- EYS | c.1767-7244G>C | Intron (SNP) | VAF 49/258 reads (19%) | called by muse, mutect2, varscan2
- FAM21FP | n.342G>A | RNA (SNP) | VAF 59/429 reads (14%) | called by muse, mutect2, varscan2
- PPM1N | c.940-268A>C | Intron (SNP) | VAF 14/106 reads (13%) | called by muse, mutect2
- PRKRA | c.-58_-41del | 5'UTR (DEL) | VAF 32/197 reads (16%) | called by mutect2, pindel, varscan2
- WDR11 | c.3291+40G>A | Intron (SNP) | VAF 89/401 reads (22%) | catalogued as rs749856052; called by muse, mutect2, varscan2
